CCDI case PBCHAS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/d095386f-73fa-4d9c-a243-c34744c2c1ea

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 3.2 years (1,159 days).

Biospecimens (3 samples)
- Sample 0DS52F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS531: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS540: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
